CCDI case PBCJJJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b21c03d2-d4e6-4b3b-b953-dc36e92fe2e5

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,331 days).

Biospecimens (3 samples)
- Sample 0DT9N0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT9ND: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DT9NQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
